Somatic mutation profile of cancer-model specimen HCM-CSHL-0075-C25-85A (3D Organoid; aliquot HCM-CSHL-0075-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0075-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen HCM-CSHL-0075-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4b7b7a8-a497-4991-86ee-f89d5c995df6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0075-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0075-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6cf1a8-9a49-46ea-b6bb-2d5c191ea6c7

The open-access MAF lists 90 somatic variants for this specimen: 50 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 30, Intron 4, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, Frame Shift Del 2, 3'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 345/529 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSG | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775538549; called by muse, mutect2, varscan2
- ASCL4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs746756373, COSV100661143; called by muse, mutect2, varscan2
- CDC23 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 129/265 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs767960544; called by muse, mutect2, varscan2
- CHP1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs368755434; called by muse, mutect2, varscan2
- CNOT1 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1329047920, COSV55316140; called by muse, mutect2, varscan2
- CTAG2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 340/346 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1557241350, COSV55995959; called by muse, mutect2, varscan2
- CYFIP2 | c.2539G>A p.A847T (on ENST00000616178 / NM_001291722.2; = p.A822T on NM_014376.4) | Missense Mutation (SNP) | VAF 153/411 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1347728182; called by muse, mutect2, varscan2
- CYP1B1 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 249/496 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as CD091791, CD147585; called by muse, mutect2, varscan2
- CYP24A1 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 486/1003 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as rs763084124, COSV53775322; called by muse, mutect2, varscan2
- DHX8 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1279076939; called by muse, mutect2, varscan2
- DNM3 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 134/574 reads (23%) | catalogued as rs768922405, COSV62470795; called by muse, mutect2, varscan2
- EXOC7 | c.1489G>T p.G497C (on ENST00000335146 / NM_001145297.4; = p.G415C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 410/418 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58740921; called by muse, mutect2, varscan2
- HIP1R | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772173203, COSV53440780; called by muse, mutect2, varscan2
- HOXA3 | c.904del p.Q302Rfs*74 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs761726531; called by mutect2, varscan2
- ITIH6 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as rs148510676; called by muse, mutect2, varscan2
- LTF | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs199748853; called by muse, mutect2, varscan2
- OR11L1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536790643, COSV63313548; called by muse, mutect2, varscan2
- PARS2 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781329433; called by muse, mutect2, varscan2
- PCDHB15 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 493/1267 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as rs868929992, COSV50867243; called by muse, mutect2, varscan2
- PDXDC1 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1193052108, COSV57911291; called by muse, mutect2, varscan2
- PIGV | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200014772; called by muse, mutect2, varscan2
- PLEKHF1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 228/402 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs760871091; called by muse, mutect2, varscan2
- SALL1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757169483; called by muse, mutect2, varscan2
- SASH1 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 120/186 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1401416180; called by muse, mutect2, varscan2
- SIGLEC6 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 211/850 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs368576884; called by muse, mutect2, varscan2
- TP53 | c.192del p.R65Efs*58 | Frame Shift Del (DEL) | VAF 243/336 reads (72%) | catalogued as CD065798; called by mutect2, pindel, varscan2
- WDR1 | c.613G>A p.A205T (on ENST00000382452; = p.A65T on NM_005112.5) | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1344929229; called by muse, mutect2, varscan2
- WDR64 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 115/190 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as rs536501700, COSV63794724, COSV63798995; called by muse, mutect2, varscan2
- ANTXRL | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 125/256 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 493/1278 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BEND3 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); called by muse, mutect2
- COL6A1 | c.1218A>T p.K406N | Missense Mutation (SNP) | VAF 305/781 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DNAH11 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- KLHL23 | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- KMT2C | c.13174C>A p.P4392T | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- LGR6 | c.1948G>C p.V650L (on ENST00000367278 / NM_001017403.1; = p.V598L on NM_021636.3) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.31); called by muse, mutect2
- LRFN1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PDE5A | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PPP1R15A | c.1911_1913del p.S638del | In Frame Del (DEL) | VAF 58/388 reads (15%) | called by pindel, varscan2
- PSMD12 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PYROXD1 | c.1340T>A p.I447N | Missense Mutation (SNP) | VAF 244/856 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- R3HCC1 | c.812C>A p.A271D (on ENST00000411463; = p.A231D on NM_001136108.3) | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, varscan2
- RAMP3 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2
- RNF19B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 278/661 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SEPTIN4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SLC46A3 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TAZ | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 233/234 reads (100%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D8 | c.2239T>G p.F747V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF816 | c.939C>G p.Y313* | Nonsense Mutation (SNP) | VAF 86/501 reads (17%) | called by muse, mutect2, varscan2
- ADGRF4 | c.339A>T p.P113= | Silent (SNP) | VAF 199/318 reads (63%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.600G>A p.G200= | Silent (SNP) | VAF 231/699 reads (33%) | called by muse, mutect2, varscan2
- C10orf90 | c.1773G>T p.L591= | Silent (SNP) | VAF 317/732 reads (43%) | called by muse, mutect2, varscan2
- C19orf47 | c.390C>T p.G130= | Silent (SNP) | VAF 60/277 reads (22%) | catalogued as rs746475267; called by muse, mutect2, varscan2
- CATSPER1 | c.1833G>A p.K611= | Silent (SNP) | VAF 397/1007 reads (39%) | called by muse, mutect2, varscan2
- CERS1 | c.684C>T p.R228= | Silent (SNP) | VAF 80/186 reads (43%) | catalogued as rs761091051; called by muse, mutect2, varscan2
- CES3 | c.465C>T p.G155= | Silent (SNP) | VAF 226/227 reads (100%) | catalogued as rs144817489; called by muse, mutect2, varscan2
- DOCK8 | c.4977G>T p.T1659= | Silent (SNP) | VAF 221/393 reads (56%) | catalogued as COSV66620803; called by muse, mutect2, varscan2
- DR1 | c.114G>C p.L38= | Silent (SNP) | VAF 302/540 reads (56%) | called by muse, mutect2, varscan2
- GRK7 | c.69G>A p.S23= | Silent (SNP) | VAF 168/330 reads (51%) | catalogued as rs1409696087; called by muse, mutect2, varscan2
- HR | c.2823T>G p.A941= | Silent (SNP) | VAF 310/705 reads (44%) | called by muse, mutect2, varscan2
- LGALS7B | c.177G>A p.E59= | Silent (SNP) | VAF 818/1990 reads (41%) | catalogued as rs754970885; called by muse, varscan2
- MAN2A2 | c.2631G>T p.R877= | Silent (SNP) | VAF 32/362 reads (9%) | called by muse, mutect2
- MKRN3 | c.114C>T p.S38= | Silent (SNP) | VAF 48/614 reads (8%) | catalogued as rs143204731, COSV100090930; called by muse, mutect2
- MYO16 | c.4935G>A p.A1645= | Silent (SNP) | VAF 109/404 reads (27%) | catalogued as COSV100697003, COSV62758718; called by muse, mutect2, varscan2
- NHLH1 | c.75C>T p.D25= | Silent (SNP) | VAF 60/1212 reads (5%) | called by muse, mutect2
- NOG | c.594G>A p.V198= | Silent (SNP) | VAF 79/80 reads (99%) | called by muse, mutect2, varscan2
- OPN5 | c.537C>T p.F179= | Silent (SNP) | VAF 86/321 reads (27%) | catalogued as rs755793601, COSV55245155; called by muse, mutect2, varscan2
- PAQR8 | c.45C>T p.S15= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs764753544, COSV62442504; called by muse, mutect2, varscan2
- PARD6G | c.1078C>T p.L360= | Silent (SNP) | VAF 7/185 reads (4%) | catalogued as rs927673676, COSV62061010; called by muse, mutect2
- PIK3R5 | c.1602G>A p.A534= | Silent (SNP) | VAF 264/521 reads (51%) | catalogued as rs200430963; called by muse, mutect2, varscan2
- PUS1 | c.684G>A p.T228= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as rs550406574, COSV59036607; ClinVar: likely benign; called by muse, mutect2
- ROCK1 | c.996C>A p.I332= | Silent (SNP) | VAF 359/496 reads (72%) | called by muse, mutect2, varscan2
- SCARA5 | c.423G>A p.A141= | Silent (SNP) | VAF 69/142 reads (49%) | catalogued as rs372992077; called by muse, mutect2, varscan2
- SLC30A4 | c.81C>T p.S27= | Silent (SNP) | VAF 190/438 reads (43%) | catalogued as rs749499477; called by muse, mutect2, varscan2
- STAC3 | c.1074C>G p.T358= | Silent (SNP) | VAF 299/617 reads (48%) | catalogued as COSV60414798; called by muse, mutect2, varscan2
- TDRD1 | c.1722C>T p.V574= | Silent (SNP) | VAF 76/164 reads (46%) | catalogued as rs201880270; called by muse, mutect2, varscan2
- TENM4 | c.5721C>T p.Y1907= | Silent (SNP) | VAF 129/334 reads (39%) | catalogued as rs768735704, COSV53625388; called by muse, mutect2, varscan2
- TUT1 | c.69T>C p.V23= | Silent (SNP) | VAF 42/99 reads (42%) | called by muse, varscan2
- ZNF211 | c.66G>T p.A22= | Silent (SNP) | VAF 259/516 reads (50%) | called by muse, mutect2, varscan2
- A4GALT | c.-40C>T | 5'UTR (SNP) | VAF 111/266 reads (42%) | catalogued as rs201433658; called by muse, mutect2, varscan2
- CD177 | c.379+13G>A | Intron (SNP) | VAF 34/478 reads (7%) | catalogued as rs1481526715; called by muse, mutect2
- DNAJC24 | c.250+16G>C | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- EIF2B4 | c.*33T>G | 3'UTR (SNP) | VAF 272/520 reads (52%) | catalogued as rs1247859477; called by muse, mutect2, varscan2
- EIF2B4 | c.32-37C>T | Intron (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- FCRL6 | c.-26C>T | 5'UTR (SNP) | VAF 259/432 reads (60%) | called by muse, mutect2, varscan2
- PEG10 | c.*1060G>A | 3'UTR (SNP) | VAF 82/1054 reads (8%) | called by muse, mutect2
- POM121C | chr7:75416000 del G | 3'Flank (DEL) | VAF 337/639 reads (53%) | called by mutect2, pindel, varscan2
- SLC16A7 | c.217+15075C>A | Intron (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- TEX21P | n.1336A>G | RNA (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
